Surgical pathology report (de-identified scan), TCGA case TCGA-77-A5G6, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-A5G6-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

No
Carcinoma, Squamous cell
8070/3

Site R Lung, upper lobe
C34.1

9/20 2/7/13

Histopathology Report

HISTORY

No clinical notes.

MACROSCOPIC

Three specimens received

1: The specimen is labelled 'right upper lobe' and consists of a lobe of lung that has been previously sampled for research purposes. This lobe measures 140 mm (SI), 20 mm (ML) and 180 mm (AP). There is puckering of the pleural surface on the anterolateral surface measuring up to 25 x 20 mm. Scarring is noted on the posterolateral surface measuring up to 10 x 10 mm. The apex shows some emphysematous changes. On sectioning a firm cream tan tumour with black pigmentation is identified within the lung parenchyma. It has a maximum cut surface area of 32 x 20 mm in dimension. The tumour is located 30 mm away from the bronchial resection margin. It is located within 1 mm of the pleural surface. [Representative sections: 1A, bronchial resection margin; 1B, peribronchial node bisected; 1C-D, one node bisected, one slice each block; 1E, one node bisected; 1F, sections of tumour nearest to pleural surface; 1G, tumour; 1H, tumour and the surrounding lung parenchyma; 1I, lung with emphysematous changes; 1J, scarring of lung; 1K, presumed normal lung tissue; 1L, further bronchial margin.]

2: The specimen is labelled 'hilar lymph node' and consists of a lymph node measuring 5 x 3 x 3 mm in dimension. [Bisected and BIT: 2A]

3: The specimen is labelled 'No 4 and No 10 lymph node' and consists of multiple pieces of yellow brown tissue ranging in size from smallest 5 x 3 x 3 mm to largest 32 x 25 x 20 mm. The largest node appears to be involved with tumour. No extra capsular spread identified. [3A, four possible nodes; 3B-C 1RS of largest node]

MICROSCOPIC

1: Sections reveal a poorly differentiated squamous cell carcinoma showing areas of clear cell change. The tumour does not directly invade visceral pleura. There is extensive lymphatic invasion with tumour present in adjacent lymphatic channels within pleura, pulmonary septa and along the course of bronchovascular bundles. Tumour is present within a lymphatic vessel at the bronchial resection margin. No tumour is identified within bronchial wall at the bronchial resection margin. The peribronchial lymph nodes are involved by tumour. The tumour deposits are present within afferent lymphatic channels, subcapsular sinuses, and are also distributed throughout lymph node parenchyma. Lymph node tissue also shows reactive changes with sinus histiocytosis, carbon pigment deposition, scattered flecks of birefringent material consistent with silicate, and hyalinized silicotic nodules. No vascular invasion or perineural permeation by tumour is seen. Immediately adjacent to the tumour there is a

[page 2 of 2]
localised area of endogenous lipoid pneumonia. Remaining lung parenchyma shows emphysema and respiratory bronchiolitis. Vascularised pleural adhesions are also present.

2: Sections reveal lymph node tissue which is partially involved by squamous cell carcinoma showing clear cell change.

3: All sections (3A-3C) reveal lymph node tissue which is partially involved by squamous cell carcinoma showing clear cell change. Lymph node tissue also shows reactive changes with follicular hyperplasia, sinus histiocytosis, carbon pigment deposition, scattered flecks of birefringent material consistent with silicate, and hyalinized silicotic nodules.

SUMMARY

1-3: Right upper lobectomy with separately submitted hilar lymph node and No. 4&10 lymph nodes:

Poorly differentiated squamous cell carcinoma with clear cell change.

Tumour size: 32mm.

Tumour does not directly invade visceral pleura.

Extensive lymphatic invasion present (within pleura, pulmonary septa and along bronchovascular bundles).

No vascular invasion or perineural permeation seen.

Tumour within lymphatic channel at bronchial resection margin; no tumour within bronchial wall at resection margin.

Peribronchial lymph nodes and separately submitted lymph nodes involved by tumour.

Pathological stage: T2 N2.

Emphysema, respiratory bronchiolitis.

Reported

T-28000 M-80703 P1-03000

	ANATOMICAL PATHOLOGY
Copy sent	

Per TSS, No clear cell carcinoma.

Criteria	lw 4/5/13	Yes	No

Source: NCI Genomic Data Commons file 1e0b07b5-627a-4c27-9c74-9f72717c4958 (TCGA-77-A5G6.1F983196-D523-4261-853B-98107B91F92D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).